Gene-level copy-number profile of tumor specimen TCGA-CM-6675-01A from TCGA case TCGA-CM-6675, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVB; Age at diagnosis: 35.4 years (12,935 days).
Specimen TCGA-CM-6675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a8a3486a-f9f6-4b5f-ad63-54ac578163e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-6675-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa31d40d-65f4-41a2-889a-5de5fb88110c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 11,213; copy number 2: 46,361; copy number 3: 2,025; copy number 4: 202.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-6675-01A-11D-1834-01): tumor purity 0.93, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,730,055–60,732,636, 2 genes: AC104164.1, PPIAP71.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,389,567–48,578,088, 7 genes: LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
